Gene-level copy-number profile of tumor specimen TCGA-MN-A4N5-01A from TCGA case TCGA-MN-A4N5, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.7 years (23,257 days).
Specimen TCGA-MN-A4N5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.34990d16-8a9e-4f5c-8fb9-7b00ee03f772.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MN-A4N5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b83494a-430f-4c60-8f1f-7c7b6bbc5878

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,447; copy number 2: 15,937; copy number 3: 21,025; copy number 4: 13,391; copy number 5: 3,809; copy number 6: 3,514; copy number 7: 294; copy number 8: 156; copy number 9: 6; copy number 10: 68; copy number 11: 37; copy number 12: 1; copy number 15: 46; copy number 20: 34; copy number 31: 3; copy number 34: 11; copy number 39: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MN-A4N5-01A-11D-A24O-01): tumor purity 0.38, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 682 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:195,003,711–195,026,370, 1 gene, copy number 12: AC010983.1.
- chr3:80,602,716–80,789,388, 3 genes, copy number 8: AC108690.1, AC068756.1, LINC02050.
- chr3:84,881,984–86,074,429, 5 genes, copy number 7 (within-gene range 3–7): LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2.
- chr4:63,128,311–66,431,521, 32 genes, copy number 7: AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3.
- chr5:55,530,156–57,534,504, 46 genes, copy number 10 (within-gene range 3–10): RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17, LINC01948, AC008391.1, RPL26P19, C5orf67, AC022431.1, AC008940.1, MAP3K1, AC008937.2, AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1, AC025470.2, SALL4P1, ACTBL2.
- chr7:62,275,361–62,275,678, 1 gene, copy number 9: AC128676.1.
- chr8:41,261,962–46,638,886, 83 genes, copy number 8 (broad region; genes not listed).
- chr12:20,695,332–21,775,600, 20 genes, copy number 7: SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8.
- chr12:21,828,360–21,828,564, 1 gene, copy number 7: AC008250.2.
- chr12:25,108,289–31,201,235, 117 genes, copy number 7–15 (within-gene range 3–15) (broad region; genes not listed).
- chr12:57,738,013–58,813,060, 30 genes, copy number 7–39 (within-gene range 2–39): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr16:62,596,372–62,598,449, 1 gene, copy number 7: AC009110.1.
- chr16:75,228,181–76,928,169, 46 genes, copy number 7 (within-gene range 2–7): BCAR1, AC009078.3, RNU6-758P, CFDP1, AC009054.1, AC009054.2, AC009163.2, AC009163.5, AC009163.7, TMEM170A, AC009163.4, CHST6, AC009163.1, AC009163.6, TMEM231P1, AC009163.3, CHST5, TMEM231, AC025287.1, AC025287.2, GABARAPL2, AC025287.3, ADAT1, KARS1, AC025287.5, TERF2IP, AC025287.4, DUXB, RN7SL520P, ATP5PBP7, CPHXL, AC105430.1, RNA5SP430, AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1.
- chr18:32,412,214–36,829,216, 61 genes, copy number 15–34 (broad region; genes not listed).
- chr19:35,248,330–35,964,063, 65 genes, copy number 8 (broad region; genes not listed).
- chr19:36,916,329–37,130,368, 5 genes, copy number 8 (within-gene range 2–8): ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2.
- chr21:20,597,953–21,543,329, 5 genes, copy number 9 (within-gene range 6–9): AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1.
- chr21:33,503,931–41,282,530, 160 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
